Surgical pathology report (de-identified scan), TCGA case TCGA-IN-8663, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-IN-8663-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

PART 1: LIVER, BIOPSY –

BILE DUCT ADENOMA, 0.3 CM (See Comment).

PART 2: LIVER, BIOPSY –

PORTION OF LIVER WITH MICROHAMARTOMA AND SUBCAPSULAR FIBROSIS (See Comment).

PART 3: PARAESOPHAGEAL LYMPH NODE NEAR INFERIOR PULMONARY VEIN, DISSECTION –

ONE BENIGN LYMPH NODE (0/1).

PART 4: ESOPHAGUS, ESOPHAGOGASTRECTOMY –

- A. POORLY DIFFERENTIATED ADENOCARCINOMA (4.0 CM) WITH SIGNET RING CELL AND NEUROENDOCRINE FEATURES, LOCATED AT THE GASTROESOPHAGEAL JUNCTION AND INVOLVING THE MUSCULARIS PROPRIA.**
- B. INTESTINAL METAPLASIA WITHIN THE STOMACH AND GASTROESOPHAGEAL JUNCTION PRESENT.**
- C. ANGIOLYMPHATIC INVASION IS PRESENT.**
- D. NO PERINEURAL INVASION IDENTIFIED.**
- E. SURGICAL RESECTION MARGINS NEGATIVE FOR CARCINOMA.**
- F. ONE OF THREE LYMPH NODES, POSITIVE FOR METASTATIC CARCINOMA (1/3).**
- G. PATHOLOGIC STAGE = pT2N3.**

PART 5: FAT PAD LYMPH NODE, DISSECTION –

FIBROADIPOSE TISSUE WITH FAT NECROSIS AND MILD HEMORRHAGE.

PART 6: SUBCARINAL LYMPH NODE, DISSECTION –

ONE BENIGN LYMPH NODE (0/1).

PART 7: LEVEL 7 LYMPH NODE, DISSECTION –

ONE BENIGN LYMPH NODE (0/1).

PART 8: SUBCARINAL LYMPH NODE NEAR AZYGOUS, DISSECTION –

ONE BENIGN LYMPH NODE (0/1).

PART 9: SUBCARINAL LYMPH NODE NEAR LEFT MAIN BRONCHUS, DISSECTION –

ONE BENIGN LYMPH NODE (0/1).

PART 10: SUBCARINAL LYMPH NODE NEAR RIGHT MAIN BRONCHUS, DISSECTION –

ONE BENIGN LYMPH NODE (0/1).

PART 11: SUBCARINAL LYMPH NODE ON ESOPHAGUS, DISSECTION –

ONE BENIGN LYMPH NODE (0/1).

PART 12: GASTROESOPHAGEAL FAT –

NINE OF FOURTEEN LYMPH NODES, POSITIVE FOR METASTATIC CARCINOMA (9/14).

PART 13: GASTRIC RINGS, EXCISION –

BENIGN ESOPHAGEAL AND GASTRIC TISSUE.

PART 14: FINAL GASTRIC MARGINS, EXCISION –

BENIGN GASTRIC TISSUE.

COMMENT:

Liver biopsies are negative for iron and PAS-D, whereas Trichrome stain shows subcapsular fibrosis.

[page 2 of 2]
MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

Stain	Result
Synaptophysin	Focal positive suggesting neuroendocrine features of carcinoma.
Chromogranin	Negative.
CD56	Negative.
MUC-2	Focal positive for residual intestinal metaplasia.
MUC-5	Positive foveolar cells.
CDX-2	Positive.
CK20	Positive.
CK7	Positive.
PAS-D/Alcian blue	Positive goblet cells.
Mucicarmine	Positive goblet cells.

The following statement applies to all immunohistochemistry, insitu hybridization (ISH & FISH), molecular anatomic pathology, and immunofluorescence testing:

The testing was developed and its performance characteristics determined by [REDACTED] required by the CLIA [REDACTED] regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of 2 to a maximum of 84 hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY ESOPHAGEAL TUMORS****----- MACROSCOPIC -----**

SPECIMEN TYPE: Esophagogastrectomy
TUMOR SITE: Esophagogastric junction (EGJ) region (tumor involves EGJ and epicenter within 5cm of EGJ)
TUMOR SIZE: Greatest dimension: 4.0 cm

----- MICROSCOPIC -----

HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE: G3
PATHOLOGIC STAGING (pTNM)
pT2
pN3
Number of lymph nodes examined: 24
Number of lymph nodes involved: 10
pM Not applicable
PRIOR TREATMENT: No prior treatment
MARGINS
Proximal margin uninvolved by invasive carcinoma
Distal margin uninvolved by invasive carcinoma
Circumferential (adventitial) margin uninvolved by invasive carcinoma
ANGIOLYMPHATIC INVASION: Present
ADDITIONAL PATHOLOGIC FINDINGS: Intestinal metaplasia (Barrett's esophagus)

Source: NCI Genomic Data Commons file dab069ec-cdba-4f42-8cc3-cc3ff7a35527 (TCGA-IN-8663.FBA4CDDF-B801-4DD0-BB6E-A571EF97424D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).